Somatic mutation profile of tumor specimen ASCProject_0113_T1_WES (aliquot ASCProject_0113_T1_WES_1) from CMI case ASCProject_0113, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Skin of scalp and neck; Age at diagnosis: 35.8 years (13,091 days).
Specimen ASCProject_0113_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head, Face or Neck, NOS; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17107647-42c1-4355-b0e4-eb465de7a01a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0113_SALIVA (Saliva), aliquot ASCProject_0113_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff8f40fc-9fe7-4948-a01a-de5679cffbe3

The open-access MAF lists 127 somatic variants for this specimen: 79 protein-altering or splice-affecting, 31 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 31, Intron 11, Nonsense Mutation 4, 3'UTR 2, RNA 2, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 29/805 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA12 | c.7393G>A p.G2465R (on ENST00000272895 / NM_173076.3; = p.G2147R on NM_015657.3) | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55960003; called by muse, mutect2
- ARFGEF2 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 19/420 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100904086, COSV64213383; called by muse, mutect2
- ASAH2 | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 19/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100270166; called by muse, mutect2
- BTD | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 23/390 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1559599486; called by muse, mutect2
- BTK | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM993330, COSV58117856; called by muse, mutect2
- DNAJC22 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as rs1250430878; called by muse, mutect2
- EGFR | c.2824G>A p.D942N | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs967910623; called by muse, mutect2
- ERN2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 17/436 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV56833909, COSV56838093; called by muse, mutect2
- FGFR2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 22/593 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV60652537; called by muse, mutect2
- MINDY4 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1293979371; called by muse, mutect2
- MUC5B | c.7706C>T p.S2569F | Missense Mutation (SNP) | VAF 34/700 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.353); catalogued as COSV71590617; called by muse, mutect2
- NCKAP5 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV58447028; called by muse, mutect2
- OR4A15 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as rs1423687925, COSV59033796, COSV59035039; called by muse, mutect2
- OR51E1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.641); catalogued as rs1007344829; called by muse, mutect2
- OR5J2 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1364673970, COSV56620315; called by muse, mutect2
- PLEKHH1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs1262695658; called by muse, mutect2
- RIMS1 | c.4579C>T p.Q1527* | Nonsense Mutation (SNP) | VAF 20/445 reads (4%) | catalogued as COSV53476486; called by muse, mutect2
- ROR2 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65223378; called by muse, mutect2
- SGCA | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 20/530 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs886044382; ClinVar: uncertain significance; called by muse, mutect2
- SGCG | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 26/610 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs1318222608; called by muse, mutect2
- SKIDA1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1477032834; called by muse, mutect2
- XIRP2 | c.2833C>T p.H945Y (on ENST00000628543; = p.H1120Y on NM_152381.6) | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV54693856, COSV54737225; called by muse, mutect2
- ZC3H18 | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 22/240 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1299875012; called by muse, mutect2
- ZFYVE21 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 16/201 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV52448859; called by muse, mutect2
- ZNF75D | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.481); catalogued as COSV66133691; called by muse, mutect2
- ARIH2 | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.956); called by muse, mutect2
- ATP1A3 | c.1718C>T p.A573V (on ENST00000545399 / NM_001256214.2; = p.A560V on NM_152296.5) | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.028); called by muse, mutect2
- ATRX | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 24/348 reads (7%) | called by muse, mutect2
- BTN2A1 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 30/457 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.781); called by muse, mutect2
- C16orf54 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 26/635 reads (4%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.025); called by muse, mutect2
- CACNA1H | c.5617G>A p.D1873N | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- CACNA2D1 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); called by muse, mutect2
- CHD5 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2
- DDX4 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DMWD | c.1654G>A p.G552S | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.113); called by muse, mutect2
- FOXP2 | c.1976_1977insGT p.S659Rfs*21 | Frame Shift Ins (INS) | VAF 20/295 reads (7%) | called by muse*, mutect2
- FOXP2 | c.1978_1979del p.P660Gfs*23 | Frame Shift Del (DEL) | VAF 21/305 reads (7%) | called by muse*, mutect2
- GRK2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2
- HEATR1 | c.3584C>T p.S1195F | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2
- HIVEP2 | c.3883C>T p.P1295S | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- IMPACT | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ITGAD | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- KIF24 | c.1753C>T p.P585S | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KRTAP10-7 | c.627C>A p.C209* | Nonsense Mutation (SNP) | VAF 36/720 reads (5%) | called by muse, mutect2
- LAMB4 | c.4198C>A p.H1400N | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- MATN3 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 19/502 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.014); called by muse, mutect2
- MFN2 | c.2163T>G p.I721M | Missense Mutation (SNP) | VAF 24/676 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2
- MICAL2 | c.3836C>G p.S1279C | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.943); called by muse, mutect2
- MYH4 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- MYO1F | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 34/624 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NNT | c.1956G>T p.M652I | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0.023); called by muse, mutect2
- NPC1L1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- PAK2 | c.1388T>G p.L463R | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PGAP1 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- PGS1 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.124); called by muse, mutect2
- PLEKHH1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2
- PLXNC1 | c.3046C>T p.L1016F | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PORCN | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); called by muse, mutect2
- PRKG2 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 27/550 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- PRLR | c.1435G>A p.V479I | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2
- PTK7 | c.2749G>A p.G917S | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTK7 | c.2750G>A p.G917D | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRJ | c.2338G>C p.V780L | Missense Mutation (SNP) | VAF 34/625 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.392); called by muse, mutect2
- ROBO1 | c.2221C>T p.L741F | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC26A3 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.802); called by muse, mutect2
- SLC35G4 | c.179T>A p.M60K | Missense Mutation (SNP) | VAF 19/386 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- STX1A | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.087); called by muse, mutect2
- STXBP1 | c.1723C>T p.P575S | Missense Mutation (SNP) | VAF 26/676 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SYNGAP1 | c.2893C>T p.H965Y | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.147); called by muse, mutect2
- TLR10 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); called by muse, mutect2
- TOPAZ1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 15/379 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.029); called by muse, mutect2
- TPO | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2
- TSEN2 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2
- WDR7 | c.1281T>G p.D427E | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- ZBTB12 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZFP57 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 24/598 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- ZFPL1 | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 18/377 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- ZNF334 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCD3 | c.1731A>G p.Q577= | Silent (SNP) | VAF 12/352 reads (3%) | called by muse, mutect2
- ALDH1B1 | c.90G>A p.L30= | Silent (SNP) | VAF 13/298 reads (4%) | called by muse, mutect2
- ARAP2 | c.4857G>A p.K1619= | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as COSV58284361; called by muse, mutect2
- ATP1A3 | c.1719C>T p.A573= (on ENST00000545399 / NM_001256214.2; = p.A560= on NM_152296.5) | Silent (SNP) | VAF 15/334 reads (4%) | called by muse, mutect2
- CDK5RAP2 | c.453G>A p.K151= | Silent (SNP) | VAF 26/530 reads (5%) | catalogued as COSV62578044; called by muse, mutect2
- COL24A1 | c.879C>T p.I293= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV65304906, COSV65309491, COSV65314542; called by muse, mutect2
- DNAI1 | c.1440G>A p.V480= | Silent (SNP) | VAF 25/636 reads (4%) | catalogued as rs1186642679, COSV54283365; called by muse, mutect2
- EARS2 | c.1254C>T p.S418= | Silent (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- ERGIC3 | c.84C>T p.A28= | Silent (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- GABRA4 | c.762G>A p.R254= | Silent (SNP) | VAF 12/247 reads (5%) | catalogued as COSV51933936; called by muse, mutect2
- GRM7 | c.804T>C p.D268= | Silent (SNP) | VAF 20/269 reads (7%) | called by muse, mutect2
- IGSF5 | c.606C>T p.I202= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as rs1036593668; called by muse, mutect2
- JAK3 | c.1251C>T p.V417= | Silent (SNP) | VAF 24/452 reads (5%) | called by muse, mutect2
- LRP8 | c.1866C>T p.I622= | Silent (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- MECOM | c.1113C>T p.L371= (on ENST00000468789 / NM_001105078.4; = p.L559= on NM_004991.4) | Silent (SNP) | VAF 9/192 reads (5%) | catalogued as COSV52973818; called by muse, mutect2
- MYBL2 | c.807C>A p.P269= | Silent (SNP) | VAF 18/579 reads (3%) | called by muse, mutect2
- MYO1F | c.2277G>A p.R759= | Silent (SNP) | VAF 36/624 reads (6%) | catalogued as COSV57798320; called by muse, mutect2
- NAT10 | c.1260C>T p.G420= | Silent (SNP) | VAF 11/245 reads (4%) | called by muse, mutect2
- NLRC4 | c.1854G>A p.G618= | Silent (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- OXNAD1 | c.504C>T p.A168= | Silent (SNP) | VAF 19/350 reads (5%) | catalogued as rs1559768016; called by muse, mutect2
- PIK3R2 | c.1602G>A p.E534= | Silent (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- PLEKHH2 | c.1107G>A p.K369= | Silent (SNP) | VAF 10/207 reads (5%) | called by muse, mutect2
- PRSS35 | c.204A>G p.K68= | Silent (SNP) | VAF 9/180 reads (5%) | called by muse, mutect2
- RFX7 | c.2985C>T p.D995= (on ENST00000559447 / NM_001368074.1; = p.D1092= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- RTEL1 | c.2127C>T p.F709= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as rs866837044, BM1535360; ClinVar: likely benign; called by muse, mutect2
- SIDT1 | c.1986G>A p.R662= | Silent (SNP) | VAF 16/287 reads (6%) | catalogued as COSV53500394; called by muse, mutect2
- STXBP1 | c.1722C>T p.T574= | Silent (SNP) | VAF 25/680 reads (4%) | called by muse, mutect2
- THSD7B | c.531C>T p.P177= | Silent (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- TMEM132A | c.1095C>T p.R365= (on ENST00000453848 / NM_178031.3; = p.R366= on NM_017870.4) | Silent (SNP) | VAF 26/343 reads (8%) | called by muse, mutect2
- UHRF1BP1 | c.2923C>T p.L975= | Silent (SNP) | VAF 15/352 reads (4%) | called by muse, mutect2
- VWCE | c.1761C>T p.D587= | Silent (SNP) | VAF 18/400 reads (5%) | called by muse, mutect2
- AC018563.1 | n.692C>T | RNA (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- AP000769.5 | chr11:65499008 C>T | 5'Flank (SNP) | VAF 22/236 reads (9%) | catalogued as rs534539647; called by muse, mutect2
- BEST1 | c.867+88G>A | Intron (SNP) | VAF 28/638 reads (4%) | called by muse, mutect2
- CSF3R | c.1864+14G>A | Intron (SNP) | VAF 20/506 reads (4%) | catalogued as rs1176428882; called by muse, mutect2
- ERBB2 | c.1022-107C>T | Intron (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- GBA3 | c.59-8480C>A | Intron (SNP) | VAF 18/314 reads (6%) | catalogued as rs1359257221; called by muse, mutect2
- GET4 | c.156-1786C>T | Intron (SNP) | VAF 20/304 reads (7%) | called by muse, mutect2
- GYS2 | c.1646-38C>T | Intron (SNP) | VAF 10/189 reads (5%) | catalogued as rs1432179778; called by muse, mutect2
- MASP1 | c.1304-5268G>A | Intron (SNP) | VAF 12/192 reads (6%) | catalogued as rs1211357616; called by muse, mutect2
- MUCL3 | c.947-1087G>A | Intron (SNP) | VAF 12/382 reads (3%) | catalogued as COSV58518757; called by muse, mutect2
- OR7E5P | n.145G>A | RNA (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- PLA2G7 | c.-6C>T | 5'UTR (SNP) | VAF 14/327 reads (4%) | called by muse, mutect2
- PPOX | c.223-26C>T | Intron (SNP) | VAF 35/800 reads (4%) | called by muse, mutect2
- RUVBL2 | c.*16C>T | 3'UTR (SNP) | VAF 14/219 reads (6%) | called by muse, mutect2
- SPATA18 | c.*35G>A | 3'UTR (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- XPC | c.901-13C>T | Intron (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- XPC | c.901-14C>T | Intron (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
